Somatic mutation profile of tumor specimen TCGA-DQ-7591-01A (aliquot TCGA-DQ-7591-01A-11D-2078-08) from TCGA case TCGA-DQ-7591, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G4; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-DQ-7591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63663f0d-db1a-47c6-b41d-b20fa2da6a51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-7591-10A (Blood Derived Normal), aliquot TCGA-DQ-7591-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/939db29a-f552-469d-8fc6-3d6e9c0671ce

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABTB2 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100131851; called by muse, mutect2, varscan2
- ARID5B | c.2702C>T p.T901M | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs199637139, COSV54428630; called by muse, mutect2, varscan2
- BIK | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99295742; called by muse, mutect2, varscan2
- CA4 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV99958447; called by muse, mutect2, varscan2
- CDK15 | c.803C>T p.P268L (on ENST00000652192 / NM_001366386.2; = p.P217L on NM_139158.2) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643016, COSV99643471; called by muse, mutect2, varscan2
- COL11A1 | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100617596, COSV62197500; called by muse, mutect2, varscan2
- FAT2 | c.8069A>G p.K2690R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99943676; called by muse, mutect2, varscan2
- FBLN5 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749952010, COSV50902319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCOM1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs748202049, COSV99985153; called by muse, mutect2, varscan2
- HERC2 | c.12571-1G>A p.X4191_splice | Splice Site (SNP) | VAF 43/113 reads (38%) | catalogued as COSV55321829, COSV99875521; called by mutect2, varscan2
- JMJD7-PLA2G4B | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100584088; called by muse, mutect2, varscan2
- NOX4 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as COSV99631333; called by muse, mutect2
- OLFML2B | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99668691; called by muse, mutect2, varscan2
- PCDHA11 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as rs543880939, COSV56529710; called by muse, mutect2, varscan2
- POLB | c.61+1G>T p.X21_splice | Splice Site (SNP) | VAF 31/93 reads (33%) | catalogued as COSV99613262; called by muse, mutect2, varscan2
- QSER1 | c.2184T>A p.D728E (on ENST00000399302; = p.D857E on NM_001076786.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101234933, COSV67900039; called by muse, mutect2, varscan2
- RALGAPA2 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99174294; called by muse, mutect2
- SCN1A | c.5501C>T p.A1834V (on ENST00000303395 / NM_001202435.3; = p.A1823V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs780809852, COSV100319388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.344); catalogued as COSV99958037; called by muse, mutect2, varscan2
- SLC14A1 | c.889A>G p.M297V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100425155; called by muse, mutect2, varscan2
- SLIT2 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99885746; called by mutect2, varscan2
- SLX4 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372150541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR5 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100681977; called by muse, mutect2, varscan2
- ZNF835 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1056657792, COSV73379539; called by muse, mutect2, varscan2
- DHRS1 | c.907_922del p.K303Sfs*86 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- SMG1 | c.6163_6173del p.L2055Ifs*14 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- CDH11 | c.339C>T p.T113= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1304692255, COSV99219261; called by muse, mutect2, varscan2
- COL4A4 | c.108A>T p.V36= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100307373; called by muse, mutect2, varscan2
- ELP4 | c.402T>A p.L134= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100635752; called by muse, mutect2, varscan2
- GPAA1 | c.801G>A p.T267= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs189367473; called by muse, mutect2, varscan2
- MAP2 | c.5304T>A p.A1768= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99561101; called by muse, mutect2, varscan2
- MYH2 | c.456G>A p.P152= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs772443784, COSV55447459; called by muse, mutect2, varscan2
- SPATA31E1 | c.1677C>T p.V559= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100350104; called by muse, mutect2
- TONSL | c.3847C>T p.L1283= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99465851; called by muse, mutect2, varscan2
